CCDI case PBBINC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d3dce831-2613-49ec-a8a7-f54dd2839c54

Demographics
Sex at birth: male; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.6 years (3,124 days).

Biospecimens (3 samples)
- Sample 0D9JMW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9JN1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D9JTO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
